FM case AD11038 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/eb38b2d4-633c-49e5-a372-f028420f753b

Female, 47.9 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the thyroid gland; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
